Somatic mutation profile of tumor specimen TCGA-KN-8428-01A (aliquot TCGA-KN-8428-01A-11D-2310-10) from TCGA case TCGA-KN-8428, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 71.9 years (26,252 days).
Specimen TCGA-KN-8428-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43e4f716-3fac-4caf-95b4-cf31d5905a4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KN-8428-11A (Solid Tissue Normal), aliquot TCGA-KN-8428-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79fbf0f9-9aac-4213-a8e2-8570b037e1ef

The open-access MAF lists 802 somatic variants for this specimen: 542 protein-altering or splice-affecting, 219 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 487, Silent 219, Nonsense Mutation 35, Intron 12, 3'UTR 12, 5'UTR 8, Splice Site 8, RNA 7, Frame Shift Del 5, Splice Region 4, 5'Flank 2, Frame Shift Ins 1.

Variants (750 of 802; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPL | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as rs1057516334, CM1311294, COSV66380275; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GABRG2 | c.889G>A p.G297R (on ENST00000361925 / NM_001375343.1; = p.G257R on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs1554098235, CM155068, COSV100729751, COSV62721042; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MEGF8 | c.4697G>A p.R1566H (on ENST00000251268 / NM_001271938.2; = p.R1499H on NM_001410.3) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs397515427, CM1210238, COSV52083808; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MFRP | c.487C>T p.R163C (on ENST00000449574; = p.R539C on NM_031433.4) | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs374823079, CM155304; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3312dup p.G1105Wfs*3 | Frame Shift Ins (INS) | VAF 74/108 reads (69%) | catalogued as rs267608092; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- MYO15A | c.6863C>T p.S2288L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs886052676, COSV52753741; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- OTOA | c.1922+1G>A p.X641_splice (on ENST00000286149; = p.X627_splice on NM_144672.4) | Splice Site (SNP) | VAF 9/66 reads (14%) | catalogued as rs148690740; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC2A10 | c.1330C>T p.R444* | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | catalogued as rs370547023, CM070263; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TINF2 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 88/211 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.147); catalogued as rs121918544, CM080574, CM159757; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 56/71 reads (79%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VWF | c.7603C>T p.R2535* | Nonsense Mutation (SNP) | VAF 64/132 reads (48%) | catalogued as rs61751296, CM910408; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.3751G>A p.V1251M (on ENST00000372530 / NM_001198934.2; = p.V1223M on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs750581964, COSV55087774; called by muse, mutect2, varscan2
- ABHD17A | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.255); catalogued as rs536953984; called by muse, mutect2, varscan2
- ABTB2 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751166959; called by muse, mutect2, varscan2
- ACIN1 | c.3566C>T p.A1189V | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as rs1327766019; called by muse, mutect2, varscan2
- ADAMTS16 | c.2383T>C p.Y795H | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99940467; called by muse, mutect2
- ADGRB1 | c.2251G>A p.V751I | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.708); catalogued as rs977693674, COSV100029352; called by muse, mutect2
- ADGRL1 | c.2429G>A p.R810H (on ENST00000340736 / NM_001008701.3; = p.R805H on NM_014921.5) | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); catalogued as rs752719314, COSV61564282; called by muse, mutect2, varscan2
- ADGRL1 | c.692G>A p.R231H (on ENST00000340736 / NM_001008701.3; = p.R226H on NM_014921.5) | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751818898, COSV61564084; called by muse, mutect2, varscan2
- ADORA2A | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as rs771672458, COSV58380909; called by muse, mutect2, varscan2
- ADORA2A | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as COSV58379101; called by muse, mutect2, varscan2
- AFF3 | c.1957C>T p.R653W | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1451684970, COSV57850269; called by muse, mutect2, varscan2
- AGRN | c.4585C>T p.R1529C | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.347); catalogued as rs1310239552; called by muse, mutect2, varscan2
- AHNAK2 | c.5206G>A p.G1736S | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.509); catalogued as rs759209382; called by muse, mutect2, varscan2
- ALPK3 | c.3967G>A p.A1323T | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs957677669; called by muse, mutect2, varscan2
- ANAPC2 | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60569316; called by muse, mutect2, varscan2
- ANKRD52 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs775127313; called by muse, mutect2, varscan2
- ANKRD66 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.95); PolyPhen benign (0.014); catalogued as rs765382422; called by muse, mutect2, varscan2
- AP1M1 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs1414106796, COSV52229061; called by muse, mutect2, varscan2
- AP3M2 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as rs756052697, COSV51529483; called by muse, mutect2, varscan2
- ARFGAP3 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as rs749122444; called by muse, mutect2, varscan2
- ARHGAP33 | c.3185C>T p.P1062L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs200225433; called by muse, mutect2, varscan2
- ARHGEF18 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.446); catalogued as COSV60468993; called by muse, mutect2, varscan2
- ARHGEF18 | c.1455+1G>A p.X485_splice (on ENST00000359920 / NM_001130955.2; = p.X381_splice on NM_015318.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 40/160 reads (25%) | catalogued as COSV100149177; called by muse, varscan2
- ARHGEF2 | c.2201C>T p.P734L (on ENST00000361247 / NM_001162383.2; = p.P706L on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs768686704, COSV100560117; called by muse, mutect2, varscan2
- ARHGEF39 | c.334_335del p.R112Vfs*13 | Frame Shift Del (DEL) | VAF 26/142 reads (18%) | catalogued as rs1321569779; called by pindel, varscan2
- ATG2B | c.4601C>T p.T1534M | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs138090571, COSV104379645; called by muse, mutect2, varscan2
- ATM | c.7381C>T p.R2461C | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as rs201314561; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ATP10B | c.2381C>T p.S794L | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as rs375049408; called by muse, mutect2, varscan2
- ATP6V1B2 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.279); catalogued as COSV99369517; called by muse, mutect2, varscan2
- ATXN3L | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.428); catalogued as rs753162194, COSV66075322; called by muse, mutect2, varscan2
- ATXN7 | c.1795G>A p.V599I | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.089); catalogued as COSV55750300; called by muse, mutect2, varscan2
- AXDND1 | c.2594_2597del p.K865Rfs*59 | Frame Shift Del (DEL) | VAF 152/208 reads (73%) | catalogued as rs1430345412; called by mutect2, varscan2
- BIRC6 | c.8047A>G p.I2683V | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs951925181; called by muse, mutect2, varscan2
- BMP7 | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs1007847615; called by muse, mutect2, varscan2
- BNC2 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs769900613, COSV66156514; called by muse, mutect2, varscan2
- BRINP1 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1335835574, COSV56305906; called by muse, mutect2, varscan2
- BSG | c.506A>G p.H169R | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs767573364; called by muse, mutect2, varscan2
- BSN | c.7051C>T p.R2351W | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs370022838; called by muse, varscan2
- C12orf60 | c.359C>T p.T120M | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as rs911982779; called by muse, mutect2, varscan2
- C2orf16 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 39/51 reads (76%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV71613521; called by muse, mutect2, varscan2
- C3orf20 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs145497672; called by muse, mutect2, varscan2
- CACNA1B | c.3418C>T p.R1140C | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1310854298, COSV99495833; called by muse, mutect2, varscan2
- CACNA1S | c.3257G>A p.R1086H | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1800559, CM970210, COSV62936287; ClinVar: risk factor; called by muse, mutect2, varscan2
- CALHM1 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs779434169, COSV53296504; called by muse, mutect2, varscan2
- CBY2 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.49); PolyPhen benign (0.178); catalogued as rs1327752841, COSV60118119; called by muse, mutect2, varscan2
- CCDC112 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs745613153, COSV101100560; called by muse, mutect2, varscan2
- CCDC181 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376964448; called by muse, mutect2, varscan2
- CCDC28B | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.238); catalogued as rs371310338; called by muse, mutect2, varscan2
- CCDC33 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs201382754; called by muse, mutect2, varscan2
- CCKAR | c.901T>G p.S301A | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV99810173; called by muse, mutect2
- CCL27 | c.337T>C p.*113Rext*4 | Nonstop Mutation (SNP) | VAF 16/122 reads (13%) | catalogued as rs760208901; called by muse, mutect2, varscan2
- CDHR3 | c.2276C>T p.T759M | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs368556227; called by muse, mutect2, varscan2
- CDK6 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 96/187 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs373488172, COSV56008836; called by muse, mutect2, varscan2
- CELSR1 | c.4928G>A p.R1643Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.095); catalogued as rs368495315; called by muse, mutect2, varscan2
- CEMP1 | c.107G>A p.G36D | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1241992152; called by muse, mutect2, varscan2
- CFAP47 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs368440669; called by muse, mutect2, varscan2
- CHD3 | c.5812G>A p.A1938T (on ENST00000330494 / NM_001005273.3; = p.A1904T on NM_005852.4) | Missense Mutation (SNP) | VAF 85/97 reads (88%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs1482536453; called by muse, mutect2, varscan2
- CIDEC | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.176); catalogued as rs148744468; called by muse, mutect2, varscan2
- CLCN2 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs770808807, COSV99658195; called by muse, mutect2, varscan2
- CLHC1 | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368001227; called by muse, mutect2, varscan2
- COL23A1 | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as rs371777604; called by muse, mutect2, varscan2
- COL7A1 | c.2587C>T p.P863S | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as rs757643340, COSV60395303; called by muse, mutect2, varscan2
- COQ8B | c.1253A>G p.Q418R | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV53284714, COSV99424789; called by muse, mutect2, varscan2
- COX15 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs377568460; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPT1A | c.1832A>G p.E611G | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV99680774; called by muse, varscan2
- CPZ | c.763C>T p.R255W (on ENST00000360986 / NM_001014447.3; = p.R244W on NM_003652.3) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766742485; called by muse, mutect2, varscan2
- CRACD | c.3317C>T p.T1106M | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs770689139, COSV51727512; called by muse, mutect2, varscan2
- CRYBG1 | c.5471A>G p.Q1824R | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.37); catalogued as COSV64810311, COSV64812014; called by muse, mutect2, varscan2
- CTNNB1 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 81/179 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs200890083; called by muse, mutect2, varscan2
- CYFIP1 | c.3328C>T p.R1110C | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.791); catalogued as rs1403318284, COSV100487837; called by muse, mutect2, varscan2
- CYP27B1 | c.30A>C p.R10S | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as COSV99141523; called by muse, mutect2, varscan2
- CYP2D6 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.29); catalogued as rs773593134; called by mutect2, varscan2
- DCAF12L2 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs751386010, COSV63582105; called by muse, mutect2, varscan2
- DCHS1 | c.5198C>T p.T1733M | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs146184962; called by muse, mutect2, varscan2
- DCLK3 | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1004014654, COSV69364469, COSV69364651; called by muse, mutect2, varscan2
- DDB1 | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.268); catalogued as rs747126869, COSV57103889; called by muse, mutect2, varscan2
- DDX50 | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs997537566; called by muse, mutect2, varscan2
- DECR1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs761171326, COSV55170120; called by muse, mutect2, varscan2
- DEF8 | c.209G>A p.R70H (on ENST00000268676 / NM_207514.3; = p.R9H on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs373457887; called by muse, mutect2, varscan2
- DENND3 | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 81/156 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs764333152; called by muse, mutect2, varscan2
- DGKG | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs757617464, COSV53970087; called by muse, mutect2, varscan2
- DIS3 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs757537527, COSV100900002; called by muse, mutect2, varscan2
- DNAH1 | c.8633C>T p.T2878M | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs781146284, COSV70227624; called by muse, mutect2, varscan2
- DNAH3 | c.7262G>A p.R2421H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200916697, COSV54547235; called by muse, mutect2, varscan2
- DNAJC13 | c.4549G>A p.V1517I | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs772420158, COSV53451529; called by muse, mutect2, varscan2
- DNHD1 | c.2923G>A p.V975I | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372619391; called by muse, mutect2, varscan2
- DNMBP | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 3/8 reads (38%) | catalogued as rs771715835; called by muse, mutect2
- DOCK7 | c.4123A>G p.K1375E (on ENST00000635253 / NM_001367561.1; = p.K1344E on NM_033407.3) | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV51997066; called by muse, mutect2, varscan2
- DOLPP1 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as rs779266200, COSV59910156; called by muse, mutect2, varscan2
- DSG4 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.241); catalogued as COSV57393076; called by muse, mutect2, varscan2
- DSP | c.4565C>T p.T1522M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as rs375150075, COSV65793138, COSV65793568; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC2H1 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs761391585; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYSF | c.4865C>T p.T1622M | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs144383140; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFHB | c.2464C>T p.R822W | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs368362844; called by muse, mutect2, varscan2
- EGR4 | c.379G>A p.E127K (on ENST00000545030; = p.E24K on NM_001965.4) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); catalogued as rs370512012; called by muse, mutect2, varscan2
- EHD3 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs370790409; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1166291611, COSV57514677; called by muse, mutect2, varscan2
- ELAC2 | c.2354G>A p.R785Q | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99310300; called by muse, mutect2, varscan2
- ELAPOR1 | c.1837C>T p.R613* | Nonsense Mutation (SNP) | VAF 155/186 reads (83%) | catalogued as rs1177973060, COSV64041434; called by muse, mutect2, varscan2
- ENPP2 | c.1072G>A p.G358R (on ENST00000075322 / NM_001040092.3; = p.G410R on NM_006209.5) | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366872814, COSV50014761; called by muse, mutect2, varscan2
- ENPP2 | c.739C>T p.R247* | Nonsense Mutation (SNP) | VAF 22/59 reads (37%) | catalogued as rs776028490, COSV50038815; called by muse, mutect2, varscan2
- EP400 | c.2413G>A p.V805I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs1316464683, COSV57769463; called by muse, mutect2, varscan2
- EPHA10 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs972379828; called by muse, mutect2, varscan2
- EPPK1 | c.4607C>T p.A1536V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs782364262, COSV73262432, COSV73262441; called by muse, mutect2, varscan2
- ERBB3 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as rs77228285, COSV99031568; called by muse, mutect2, varscan2
- ERF | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1568472872; called by muse, mutect2, varscan2
- ERN2 | c.2380G>A p.V794I | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as rs144279415; called by muse, varscan2
- ESPL1 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs145536592; called by muse, mutect2, varscan2
- ETAA1 | c.2740C>T p.R914* | Nonsense Mutation (SNP) | VAF 82/101 reads (81%) | catalogued as COSV99712952; called by muse, mutect2, varscan2
- FAAP100 | c.2176G>A p.V726M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.407); catalogued as rs891148187, COSV59885087; called by muse, mutect2, varscan2
- FAM199X | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100245531; called by muse, mutect2
- FAM209B | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as rs200395408; called by muse, mutect2, varscan2
- FAM47C | c.1892G>A p.R631H | Missense Mutation (SNP) | VAF 43/48 reads (90%) | SIFT tolerated (0.74); PolyPhen benign (0.248); catalogued as rs782315658, COSV63726139; called by muse, mutect2, varscan2
- FAT3 | c.10618C>T p.R3540* | Nonsense Mutation (SNP) | VAF 41/88 reads (47%) | catalogued as COSV53074610, COSV53076172; called by muse, mutect2, varscan2
- FBN3 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as rs774085552; called by muse, mutect2, varscan2
- FBXL13 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs150674888; called by mutect2, varscan2
- FBXO24 | c.1604G>A p.R535H (on ENST00000241071 / NM_033506.3; = p.R573H on NM_012172.5) | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.024); catalogued as rs778209255, COSV53824757; called by muse, mutect2, varscan2
- FGB | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs571624045, COSV57418511, COSV57419244; called by muse, varscan2
- FLT4 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.54); PolyPhen benign (0.034); catalogued as rs774672515, COSV56108016, COSV99986456; called by muse, mutect2
- FMR1 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs782377065, COSV54422125; called by muse, mutect2
- FNDC11 | c.175C>T p.H59Y | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.431); catalogued as rs772833840; called by muse, mutect2, varscan2
- FPGS | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs939457319, COSV64675983; called by muse, mutect2, varscan2
- FTMT | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as COSV58420325; called by muse, mutect2, varscan2
- FUBP1 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.144); catalogued as rs569795654, COSV53940071; called by muse, mutect2, varscan2
- FUT2 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs374416675; called by muse, mutect2, varscan2
- FYB2 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs745529582, COSV58583278; called by muse, mutect2, varscan2
- GABRD | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 48/56 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1379512215; called by muse, mutect2, varscan2
- GAL3ST1 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.161); catalogued as rs1249003104, COSV100142966; called by muse, mutect2, varscan2
- GALNT6 | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 28/83 reads (34%) | catalogued as rs200682302; called by muse, mutect2, varscan2
- GALNT7 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs201773910, COSV99397034; called by muse, mutect2, varscan2
- GDF11 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as rs1032152294; called by muse, mutect2, varscan2
- GDI2 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 67/87 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1288272219; called by muse, mutect2, varscan2
- GLCE | c.131G>T p.S44I | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs1480205293; called by muse, mutect2, varscan2
- GLYATL3 | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT tolerated (0.16); PolyPhen benign (0.357); catalogued as rs1212566752; called by muse, mutect2, varscan2
- GNAZ | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99320364; called by muse, mutect2, varscan2
- GNPTAB | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1480305030; called by muse, mutect2, varscan2
- GOLGA2 | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as rs376675493, COSV68597256; called by muse, mutect2, varscan2
- GOLGA5 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 96/231 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as rs751943504; called by muse, mutect2, varscan2
- GPAA1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs550126943; called by muse, mutect2, varscan2
- GPR137C | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1379956962, COSV58706299; called by muse, mutect2
- GPR65 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as rs746098918, COSV50862766; called by mutect2, varscan2
- GTF2E2 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 52/145 reads (36%) | catalogued as COSV63478275; called by muse, mutect2, varscan2
- GUCA2B | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 87/103 reads (84%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as rs867354527, COSV65367901; called by muse, mutect2, varscan2
- H1-6 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 85/112 reads (76%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs746084928, COSV58091447; called by muse, mutect2, varscan2
- H2BW2 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.132); catalogued as rs782568310, COSV54583457; called by muse, mutect2, varscan2
- H3C3 | c.68C>T p.T23I | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.353); catalogued as rs769895262; called by muse, mutect2, varscan2
- HAPLN4 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs372695408; called by muse, mutect2, varscan2
- HCN4 | c.2452G>A p.G818S | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.477); catalogued as rs1427767002, COSV99983864; called by muse, mutect2, varscan2
- HDX | c.1455T>G p.T485= | Splice Region (SNP) | VAF 9/128 reads (7%) | catalogued as COSV99946836; called by muse, mutect2
- HELZ | c.2902C>T p.R968* | Nonsense Mutation (SNP) | VAF 29/92 reads (32%) | catalogued as COSV62377660; called by muse, mutect2, varscan2
- HELZ2 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs371600411; called by muse, varscan2
- HERC1 | c.7678C>T p.R2560* | Nonsense Mutation (SNP) | VAF 68/169 reads (40%) | catalogued as rs755228005; called by muse, mutect2, varscan2
- HERC2 | c.8867C>T p.T2956M | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs200987196; called by muse, mutect2, varscan2
- HFM1 | c.2257T>C p.L753= | Splice Region (SNP) | VAF 43/214 reads (20%) | catalogued as rs1392616713; called by muse, mutect2, varscan2
- HGS | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs567318549; called by muse, varscan2
- HGSNAT | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756140276; called by muse, mutect2, varscan2
- HIVEP3 | c.2965C>T p.R989W | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99911550; called by muse, mutect2, varscan2
- HMGB2 | c.150+1G>A p.X50_splice | Splice Site (SNP) | VAF 25/51 reads (49%) | catalogued as COSV99632642; called by muse, mutect2, varscan2
- HOMER2 | c.497A>G p.N166S (on ENST00000304231 / NM_199330.3; = p.N155S on NM_004839.4) | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.238); catalogued as COSV100420231; called by muse, mutect2
- HORMAD1 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750426596; called by muse, mutect2, varscan2
- HR | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs138624433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HRH3 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as rs1463959920; called by muse, mutect2, varscan2
- HS6ST3 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747297518, COSV65017001; called by muse, mutect2, varscan2
- HUWE1 | c.4601C>T p.T1534M | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV53339690; called by muse, mutect2
- ICAM4 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.353); catalogued as COSV53424218; called by muse, mutect2, varscan2
- IFT122 | c.3130G>A p.A1044T (on ENST00000348417 / NM_052989.3; = p.A985T on NM_018262.4) | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs149245630; called by muse, mutect2, varscan2
- IGF1R | c.1589+1G>A p.X530_splice | Splice Site (SNP) | VAF 12/58 reads (21%) | catalogued as rs749713600, COSV51368202; called by muse, mutect2, varscan2
- IGLC3 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 75/347 reads (22%) | PolyPhen possibly damaging (0.533); catalogued as rs747859802; called by muse, mutect2, varscan2
- IGLL5 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs534077784; called by muse, mutect2, varscan2
- IGSF3 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 61/80 reads (76%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as rs202203327, COSV59590797, COSV59591729; called by muse, mutect2, varscan2
- IGSF9 | c.2555G>A p.R852H (on ENST00000368094 / NM_001135050.2; = p.R836H on NM_020789.4) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767211801; called by muse, mutect2, varscan2
- IL1R1 | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs762031233, COSV52107914; called by muse, mutect2
- ILKAP | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1273069652, COSV54519388, COSV99610994; called by muse, mutect2, varscan2
- IMPA1 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 23/126 reads (18%) | catalogued as rs1308325707; called by muse, mutect2, varscan2
- INPP5B | c.1757C>T p.T586M (on ENST00000373023; = p.T506M on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs780542769, COSV100886586; called by muse, mutect2, varscan2
- ITGA7 | c.1774C>T p.R592C (on ENST00000555728; = p.R548C on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs146411608, COSV57697061, COSV99144133; called by muse, mutect2, varscan2
- ITGB5 | c.1522G>A p.V508M | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs576577571, COSV56149546; called by muse, mutect2, varscan2
- KCNA1 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66838775; called by muse, mutect2, varscan2
- KCNB1 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV65565835; called by muse, mutect2, varscan2
- KCNC1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 60/96 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as rs772042572; called by muse, mutect2, varscan2
- KCNJ1 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373198476, CM994546; called by muse, mutect2, varscan2
- KDELR3 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); catalogued as rs569201267, COSV53247518; called by muse, mutect2, varscan2
- KIF4A | c.1801C>T p.R601C | Missense Mutation (SNP) | VAF 62/70 reads (89%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs374256182; called by muse, mutect2, varscan2
- KIR3DL3 | c.435G>A p.W145* | Nonsense Mutation (SNP) | VAF 38/79 reads (48%) | catalogued as COSV99399785; called by muse, mutect2, varscan2
- KIRREL2 | c.362-1G>A p.X121_splice | Splice Site (SNP) | VAF 21/101 reads (21%) | catalogued as COSV99383675; called by muse, mutect2, varscan2
- KLF14 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV60588519; called by muse, mutect2
- KMT2B | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.965); catalogued as rs747219825, COSV52890416; called by muse, varscan2
- KNDC1 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs201644896; called by muse, mutect2, varscan2
- KRT15 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147023381; called by muse, mutect2, varscan2
- KRT2 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs747178935, COSV59011400; called by muse, mutect2, varscan2
- LAMB4 | c.2098G>A p.A700T | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs754196717, COSV52717261, COSV52726584; called by muse, mutect2, varscan2
- LAT2 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs369438020; called by muse, mutect2, varscan2
- LGI3 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs375380959; called by muse, mutect2, varscan2
- LMTK2 | c.3676G>A p.A1226T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs1361200386; called by muse, mutect2, varscan2
- LONP1 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as rs748543089, COSV62260658; called by muse, mutect2, varscan2
- LOXL2 | c.1618G>A p.G540R | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369018704, COSV66692546; called by muse, varscan2
- LPCAT3 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782772367, COSV54643787; called by muse, mutect2, varscan2
- LPIN3 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs754995106, COSV64719537; called by muse, mutect2, varscan2
- LRRC14 | c.1378G>A p.V460I | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.525); catalogued as rs746577507; called by muse, mutect2, varscan2
- LYG2 | c.431A>G p.H144R | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100283596; called by muse, mutect2
- MACROD2 | c.1315+1G>A p.X439_splice (on ENST00000642719; = p.X411_splice on NM_080676.6 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 35/68 reads (51%) | catalogued as COSV99428558; called by muse, mutect2, varscan2
- MALL | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99732101; called by muse, mutect2, varscan2
- MAP1A | c.7786C>T p.R2596W | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1307192029, COSV55810683; called by muse, mutect2, varscan2
- MAP3K7 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65224691; called by muse, mutect2, varscan2
- MAPK15 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs140275267, COSV100567745; called by muse, mutect2, varscan2
- MAST2 | c.1997C>T p.T666M | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs752170935; called by muse, mutect2, varscan2
- MATN2 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs377009254; called by muse, mutect2, varscan2
- MCM2 | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as rs760184067; called by muse, varscan2
- MECP2 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 97/110 reads (88%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs782239416, COSV100318448, COSV57658195; ClinVar: benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MICAL1 | c.2848G>A p.V950M | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs746442435; called by muse, mutect2, varscan2
- MICAL1 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773448261; called by muse, mutect2, varscan2
- MKI67 | c.8606C>T p.T2869M | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs371728740; called by muse, mutect2, varscan2
- MMP12 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as rs183458117, COSV58260645, COSV58261545; called by muse, mutect2, varscan2
- MPHOSPH8 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV100825005; called by muse, mutect2
- MRGBP | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs751931246, COSV65111405; called by muse, mutect2, varscan2
- MROH2A | c.3784C>T p.R1262* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as rs550071912, COSV67682144; called by mutect2, varscan2
- MRPL50 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 109/167 reads (65%) | catalogued as rs150313404; called by muse, varscan2
- MRPS30 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs61753790, COSV99138180; called by muse, mutect2, varscan2
- MSRB1 | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755400235, COSV51907241; called by muse, mutect2, varscan2
- MTUS1 | c.3776C>T p.S1259L (on ENST00000262102 / NM_001363061.1; = p.S425L on NM_020749.4) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148435996, COSV50590541; called by muse, mutect2, varscan2
- MYO18B | c.6509C>T p.S2170L | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs770881865, COSV59130091; called by muse, mutect2, varscan2
- MYO1F | c.2381G>A p.R794Q | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.184); catalogued as rs201723456, COSV100596611; called by muse, mutect2, varscan2
- MYO1H | c.2905G>A p.V969I | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs369009537, COSV57326031, COSV57326276; called by muse, mutect2, varscan2
- MYO9A | c.1424C>T p.T475M | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs148826761; called by muse, mutect2, varscan2
- MYOM2 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as rs544544159, COSV50750153; called by muse, mutect2, varscan2
- NACC1 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99456836; called by muse, mutect2
- NDC80 | c.1712C>T p.T571M | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs536241153, COSV55248651; called by muse, mutect2, varscan2
- NDE1 | c.1040G>A p.R347Q (on ENST00000577101; = p.T319= on NM_017668.3) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | PolyPhen benign (0.412); catalogued as rs369335485; called by muse, mutect2, varscan2
- NEK10 | c.2431C>T p.R811C | Missense Mutation (SNP) | VAF 44/257 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs774551711, COSV55356403, COSV99834621; called by muse, mutect2, varscan2
- NEMF | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374912149; called by mutect2, varscan2
- NF1 | c.5044T>C p.C1682R (on ENST00000358273 / NM_001042492.3; = p.C1661R on NM_000267.3) | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM137130; called by muse, mutect2, varscan2
- NFIX | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1210455175, COSV100666307; called by muse, mutect2, varscan2
- NIPBL | c.3452C>T p.P1151L | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV56943224, COSV99240463; called by muse, mutect2, varscan2
- NIPBL | c.5875G>A p.E1959K | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.046); catalogued as COSV99239470; called by muse, mutect2, varscan2
- NLRP10 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs755554745, COSV60782263; called by muse, mutect2, varscan2
- NLRP3 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 50/66 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs533920557, COSV60221235, COSV60223557; called by muse, mutect2, varscan2
- NOTCH3 | c.1918C>T p.R640C | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs760768552, CM125168; ClinVar: not provided; called by muse, mutect2, varscan2
- NSMAF | c.2381C>T p.T794M | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as rs138530641, COSV99232930; called by muse, mutect2, varscan2
- NT5C1A | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539519081, COSV52495974, COSV52497301; called by muse, mutect2, varscan2
- NTF4 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as rs200081067, COSV56825101; called by muse, mutect2, varscan2
- NTRK3 | c.2441G>A p.R814Q (on ENST00000360948 / NM_001012338.2; = p.R800Q on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1191745945, COSV62317020; called by muse, mutect2, varscan2
- NUP205 | c.3131C>T p.T1044M | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.778); catalogued as rs540996642, COSV53666661; called by muse, mutect2, varscan2
- NYNRIN | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.037); catalogued as rs1298258264, COSV66840983; called by muse, mutect2, varscan2
- OAS1 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776426424; called by muse, mutect2, varscan2
- OBSL1 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54718125; called by muse, mutect2, varscan2
- OLFM2 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1289831457; called by muse, mutect2, varscan2
- OPRK1 | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs771921471, COSV55569928; called by muse, mutect2, varscan2
- OR2A2 | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 21/108 reads (19%) | catalogued as rs536132673, COSV68872204; called by muse, mutect2, varscan2
- OR2A7 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs1315911279; called by muse, mutect2
- OR4D2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs142058863, COSV101613850; called by muse, varscan2
- OR4K13 | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs199734457; called by muse, mutect2, varscan2
- OR5AU1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs754311632, COSV100436224; called by muse, mutect2, varscan2
- OSBPL8 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 111/200 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1206488473, COSV53882841; called by muse, mutect2, varscan2
- OVOL2 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755606955, COSV53859550; called by muse, mutect2, varscan2
- OXER1 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 38/50 reads (76%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); catalogued as rs374132247; called by muse, varscan2
- PADI4 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 73/83 reads (88%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1000178880; called by muse, mutect2, varscan2
- PALD1 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs766925536, COSV54971183; called by muse, mutect2, varscan2
- PBK | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.604); catalogued as rs371557868; called by muse, mutect2, varscan2
- PCDH1 | c.3427C>T p.R1143C | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs777750122, COSV54613353; called by muse, mutect2, varscan2
- PCDHGB2 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs267600451, COSV53954198; called by muse, mutect2, varscan2
- PID1 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | PolyPhen benign (0); catalogued as rs1326829932; called by muse, mutect2, varscan2
- PIGO | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs759013444, COSV53052820; called by muse, mutect2, varscan2
- PIKFYVE | c.5396C>T p.T1799I | Missense Mutation (SNP) | VAF 55/90 reads (61%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs147015179; called by muse, mutect2, varscan2
- PITPNM1 | c.2879C>T p.T960M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.649); catalogued as rs371845321; called by muse, mutect2, varscan2
- PIWIL4 | c.2285G>A p.R762H | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs749598394; called by muse, mutect2, varscan2
- PKHD1 | c.8242G>T p.G2748C | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1172946587, COSV100581763; called by muse, mutect2
- PLA2G6 | c.1376G>A p.R459Q | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.287); catalogued as rs763827059; called by muse, mutect2, varscan2
- PLCG1 | c.2930A>G p.Y977C | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV99718622; called by muse, mutect2
- PLIN2 | c.359C>T p.T120M | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs1401915357, COSV99438755; called by muse, mutect2
- PLIN4 | c.2911G>A p.A971T (on ENST00000301286; = p.A986T on NM_001367868.2) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867896808; called by muse, mutect2, varscan2
- PLXNA2 | c.1208A>G p.N403S | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1227306007, COSV65439209; called by muse, mutect2
- PMEPA1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1197103999; called by muse, mutect2, varscan2
- POLE | c.1309G>A p.V437M | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); catalogued as rs115047349, COSV57691144; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POR | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs562750402, COSV101203715; called by muse, mutect2, varscan2
- POU2F2 | c.568C>T p.P190S (on ENST00000526816 / NM_001207025.3; = p.P174S on NM_002698.5) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.679); catalogued as rs1360694668; called by muse, mutect2, varscan2
- PPAT | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.065); catalogued as rs1172878331; called by muse, mutect2
- PPL | c.4286C>T p.A1429V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs755541914; called by muse, mutect2, varscan2
- PPM1B | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.255); catalogued as rs758211363, COSV99175734; called by muse, mutect2, varscan2
- PPOX | c.987+1G>T p.X329_splice | Splice Site (SNP) | VAF 23/43 reads (53%) | catalogued as COSV99237214; called by muse, mutect2, varscan2
- PPP1R16B | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs139690056; called by muse, mutect2, varscan2
- PPP4R2 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 112/259 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs774490422, COSV55597565; called by muse, mutect2, varscan2
- PRKAG1 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60291524; called by muse, mutect2, varscan2
- PRKN | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs756064095, CM056034; called by muse, mutect2, varscan2
- PRNP | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs776593792, CM001314; called by muse, mutect2, varscan2
- PROSER3 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.811); catalogued as rs778194260; called by muse, mutect2, varscan2
- PRPF40B | c.227C>T p.A76V (on ENST00000380281; = p.A70V on NM_012272.3) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs750265621; called by muse, mutect2, varscan2
- PRSS58 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as rs533423282; called by muse, mutect2, varscan2
- PSME3IP1 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV58430743; called by muse, mutect2, varscan2
- PTTG2 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 66/124 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs544810432; called by muse, mutect2
- R3HCC1 | c.1412G>A p.R471Q (on ENST00000411463; = p.R431Q on NM_001136108.3) | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as rs1051804607, COSV99743646; called by muse, mutect2
- RAB44 | c.2711G>A p.R904H | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs771415718; called by muse, mutect2, varscan2
- RABEPK | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs147509125; called by muse, mutect2, varscan2
- RAPGEFL1 | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754581990; called by muse, mutect2, varscan2
- RASA3 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.094); catalogued as rs370539205; called by muse, mutect2, varscan2
- RASGEF1B | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as rs985625171; called by muse, mutect2, varscan2
- RASGRP4 | c.1714C>T p.R572W | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs759183398, COSV99384879; called by muse, mutect2, varscan2
- RB1 | c.2053del p.Q685Sfs*11 | Frame Shift Del (DEL) | VAF 77/130 reads (59%) | catalogued as COSV57327652; called by mutect2, pindel, varscan2
- RBFOX2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); catalogued as rs868689309; called by muse, mutect2, varscan2
- RBM25 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.198); catalogued as rs202176813, COSV56202421, COSV56203685; called by muse, mutect2, varscan2
- RECQL5 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs199975622; called by muse, mutect2, varscan2
- RGS3 | c.3034G>A p.V1012I (on ENST00000350696 / NM_001282923.2; = p.V731I on NM_130795.4) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as rs750641666, COSV59514911; called by muse, mutect2, varscan2
- RGSL1 | c.2557G>A p.A853T | Missense Mutation (SNP) | VAF 85/107 reads (79%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV54261357; called by muse, mutect2, varscan2
- RHBDL1 | c.1255G>A p.A419T (on ENST00000219551 / NM_001318733.2; = p.A354T on NM_001278720.2) | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.937); catalogued as rs1443990973; called by muse, mutect2, varscan2
- RIMKLB | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs1424474258, COSV100223785; called by muse, mutect2, varscan2
- RNF157 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs763071977; called by muse, mutect2, varscan2
- RNF208 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.719); catalogued as COSV61286535, COSV61287029; called by muse, mutect2, varscan2
- RNF222 | c.155A>G p.D52G | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV100680360; called by muse, mutect2
- ROPN1 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 101/245 reads (41%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs140868038, COSV51739347; called by muse, mutect2, varscan2
- RPRD2 | c.4091G>A p.R1364H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.816); catalogued as rs372428982; called by mutect2, varscan2
- RREB1 | c.3296C>T p.T1099M | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs376220493; called by muse, mutect2, varscan2
- RTL1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1343427893; called by muse, mutect2, varscan2
- S100A4 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.162); catalogued as rs939819644, COSV62876679; called by muse, mutect2, varscan2
- SBF2 | c.5485G>A p.A1829T | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750660963, COSV56297723; called by muse, mutect2, varscan2
- SCGB3A1 | c.209A>G p.H70R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV99484966; called by muse, mutect2
- SEPTIN5 | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1253845004, COSV63530545; called by muse, mutect2, varscan2
- SERINC2 | c.662C>T p.A221V (on ENST00000373709 / NM_178865.5; = p.A225V on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/176 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs782011992; called by muse, mutect2, varscan2
- SEZ6L | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs996288290, COSV50662638; called by muse, mutect2, varscan2
- SGTA | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs1390800497, COSV99682515; called by muse, mutect2, varscan2
- SHC3 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.099); catalogued as rs539726812; called by muse, mutect2, varscan2
- SHLD1 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs140278441; called by muse, mutect2, varscan2
- SHROOM3 | c.5561G>A p.R1854H | Missense Mutation (SNP) | VAF 74/127 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99935289; called by muse, mutect2, varscan2
- SLC12A9 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as rs150811167, COSV51931231; called by muse, mutect2, varscan2
- SLC16A13 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs748411366; called by muse, mutect2, varscan2
- SLC22A13 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs1309350408; called by muse, mutect2, varscan2
- SLC25A6 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); catalogued as rs1247758305, COSV100452433; called by muse, mutect2, varscan2
- SLC32A1 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.048); catalogued as COSV54146738; called by muse, mutect2, varscan2
- SLC38A10 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 42/52 reads (81%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs376751634; called by muse, mutect2, varscan2
- SLC6A17 | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 66/75 reads (88%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs776745886; called by muse, mutect2, varscan2
- SLC7A1 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.8); PolyPhen benign (0.048); catalogued as rs1445256883; called by muse, mutect2
- SLC7A8 | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs752008062, COSV57553938; called by muse, mutect2, varscan2
- SLIT2 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as rs1224798825, COSV99883468; called by muse, mutect2, varscan2
- SMAD3 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV59290743; called by muse, mutect2, varscan2
- SMARCB1 | c.1004C>T p.T335M (on ENST00000263121; = p.T381M on NM_003073.5) | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1387467529, COSV51955658; called by muse, mutect2, varscan2
- SNRPB | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs778892584, COSV60015031; called by muse, mutect2, varscan2
- SNX14 | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 76/101 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1441971454; called by muse, mutect2, varscan2
- SNX25 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs140041413, COSV53014770; called by muse, mutect2, varscan2
- SPATA2 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs77667957; called by muse, mutect2, varscan2
- SPATC1 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs782224940, COSV66298002; called by muse, mutect2, varscan2
- SPTY2D1 | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs749523992, COSV100311548; called by muse, mutect2, varscan2
- SRCAP | c.7138C>T p.R2380W | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV52680434; called by mutect2, varscan2
- SRPRA | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760553374, COSV55005852; called by muse, mutect2, varscan2
- SSC5D | c.2374C>T p.R792C | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs371786822; called by muse, mutect2, varscan2
- STXBP5 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51659599; called by muse, mutect2, varscan2
- SVOP | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs764499042, COSV54468848; called by muse, mutect2, varscan2
- SYNDIG1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as rs747730431, COSV65239625; called by muse, mutect2
- SZT2 | c.4691C>T p.P1564L (on ENST00000634258 / NM_001365999.1; = p.P1507L on NM_015284.4) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1329340929, COSV65168873; called by muse, mutect2
- TARBP2 | c.134C>T p.T45M (on ENST00000266987 / NM_134323.2; = p.T24M on NM_004178.4) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as rs1162993139; called by muse, mutect2, varscan2
- TBC1D22A | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs535972526; called by muse, mutect2, varscan2
- TBC1D7 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1200325729, COSV100568697; called by muse, mutect2, varscan2
- TBL3 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.13); catalogued as rs1240230781; called by muse, mutect2, varscan2
- TBX19 | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as rs559696399, COSV100892356; called by muse, mutect2, varscan2
- TBX6 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs756921502, COSV54221741; called by muse, mutect2, varscan2
- TCF20 | c.3767G>A p.R1256H | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1024287636, COSV59495012; called by muse, mutect2, varscan2
- TCF7L1 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1464574591; called by muse, mutect2, varscan2
- TDRD9 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs1467738407, COSV59143229; called by muse, mutect2, varscan2
- TEPSIN | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs778937071; called by muse, varscan2
- TEX11 | c.358C>T p.R120* (on ENST00000344304; = p.R105* on NM_031276.3) | Nonsense Mutation (SNP) | VAF 58/168 reads (35%) | catalogued as rs1486675411, COSV60228091, COSV60228924; called by muse, mutect2, varscan2
- TEX44 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV58354560; called by muse, mutect2, varscan2
- TGM7 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs150218635; called by muse, mutect2, varscan2
- TINAG | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs752342377; called by mutect2, varscan2
- TJP1 | c.3466C>T p.R1156W | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs747859807, COSV100632126; called by muse, mutect2, varscan2
- TM4SF1 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 58/127 reads (46%) | catalogued as rs768672228; called by muse, mutect2, varscan2
- TMC2 | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 130/303 reads (43%) | catalogued as rs772286509; called by muse, mutect2, varscan2
- TMC3 | c.2110G>A p.A704T | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as rs759090667; called by muse, mutect2, varscan2
- TMEM161B | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 39/120 reads (33%) | catalogued as rs1242031227, COSV99680392; called by muse, mutect2, varscan2
- TMEM176B | c.588G>A p.M196I | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV100423541; called by muse, mutect2, varscan2
- TMEM177 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs758353670, COSV55609469; called by muse, mutect2, varscan2
- TMEM205 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 60/107 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs776246257, COSV55792351; called by muse, mutect2, varscan2
- TMPRSS12 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as rs761268109, COSV68257321; called by muse, mutect2, varscan2
- TNRC6B | c.5065C>T p.R1689* (on ENST00000454349 / NM_001162501.2; = p.R1579* on NM_015088.3) | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as COSV100109783, COSV100110742; called by muse, mutect2, varscan2
- TNRC6C | c.3040C>T p.R1014C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754305823; called by muse, mutect2, varscan2
- TONSL | c.576G>A p.A192= | Splice Region (SNP) | VAF 12/62 reads (19%) | catalogued as rs755618655; called by muse, mutect2, varscan2
- TP73 | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 39/50 reads (78%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.979); catalogued as rs146218192; called by muse, mutect2, varscan2
- TPR | c.6494G>A p.R2165Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as rs761906613; called by muse, mutect2, varscan2
- TRAF7 | c.1942G>A p.A648T | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.089); catalogued as rs1347356668; called by muse, mutect2, varscan2
- TRIM25 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.61); PolyPhen benign (0.028); catalogued as rs777785843; called by muse, mutect2, varscan2
- TRIM68 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 9/82 reads (11%) | catalogued as rs749156035, COSV100331647; called by muse, mutect2, varscan2
- TRIOBP | c.6019C>T p.R2007C (on ENST00000644935 / NM_001039141.3; = p.R294C on NM_007032.5) | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs748421941; called by muse, mutect2, varscan2
- TRPS1 | c.2666G>A p.R889H (on ENST00000220888 / NM_001330599.2; = p.R902H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs549374718, COSV55242589; called by muse, mutect2, varscan2
- TRRAP | c.8603C>T p.A2868V (on ENST00000359863 / NM_001244580.1; = p.A2850V on NM_003496.3) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as rs1325477433, COSV62840903; called by muse, mutect2, varscan2
- TSGA10IP | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs779591922, COSV73245200, COSV73245257; called by muse, mutect2, varscan2
- TSPAN14 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs754016524, COSV59367690; called by muse, mutect2, varscan2
- TSPO | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs957157767, COSV53357283; called by muse, mutect2, varscan2
- TTC8 | c.460-2A>G p.X154_splice (on ENST00000338104 / NM_001288781.1; = p.X164_splice on NM_144596.4) | Splice Site (SNP) | VAF 32/144 reads (22%) | catalogued as COSV100581148; called by muse, mutect2, varscan2
- TTN | c.52873A>G p.M17625V (on ENST00000591111; = p.M10201V on NM_003319.4) | Missense Mutation (SNP) | VAF 28/53 reads (53%) | PolyPhen benign (0.007); catalogued as rs372963343; called by muse, mutect2, varscan2
- TUBGCP6 | c.1720G>A p.V574M | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.404); catalogued as rs763691161; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBE4B | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 5/108 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53536395; called by muse, mutect2
- UBR2 | c.4120G>A p.A1374T | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs753066780; called by muse, mutect2, varscan2
- UCP2 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs145061662; called by muse, mutect2, varscan2
- UMOD | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as rs1357689052; called by muse, mutect2, varscan2
- UNC13B | c.3268C>T p.R1090* | Nonsense Mutation (SNP) | VAF 25/186 reads (13%) | catalogued as rs756943841, COSV65934103; called by muse, mutect2, varscan2
- UNC80 | c.6752G>A p.R2251H | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs1292203908; called by muse, mutect2, varscan2
- UQCRC2 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs371099781; called by muse, mutect2, varscan2
- VCAM1 | c.236C>T p.T79M | Missense Mutation (SNP) | VAF 108/139 reads (78%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.552); catalogued as rs142501320; called by muse, mutect2, varscan2
- VIRMA | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 25/133 reads (19%) | catalogued as rs774485348; called by muse, mutect2, varscan2
- VPS37C | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.226); catalogued as rs375223987; called by muse, mutect2, varscan2
- WASL | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV56135952; called by muse, mutect2, varscan2
- WBP4 | c.1114C>T p.R372* | Nonsense Mutation (SNP) | VAF 33/45 reads (73%) | catalogued as rs1437861860, COSV101069344; called by muse, mutect2, varscan2
- WDR37 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99579370; called by muse, mutect2, varscan2
- WDR7 | c.3697G>A p.E1233K | Missense Mutation (SNP) | VAF 49/260 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs766214130; called by muse, mutect2, varscan2
- WDR74 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1277136038; called by muse, mutect2, varscan2
- WFDC1 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as rs145066295; called by muse, mutect2, varscan2
- WNT2 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.154); catalogued as rs143749132, COSV55414144; called by muse, mutect2, varscan2
- WTIP | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs539423563; called by muse, mutect2, varscan2
- XRCC4 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140143447; called by muse, mutect2, varscan2
- YLPM1 | c.6425G>A p.R2142Q | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs758625730, COSV57818189; called by muse, mutect2, varscan2
- ZAN | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.553); catalogued as rs374155932; called by muse, mutect2, varscan2
- ZBTB34 | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 22/92 reads (24%) | catalogued as COSV100044002; called by muse, mutect2, varscan2
- ZFAT | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs779516150, COSV64733795; called by muse, mutect2, varscan2
- ZFP36 | c.736del p.L246Wfs*126 (on ENST00000594442; = p.L240Wfs*126 on NM_003407.5) | Frame Shift Del (DEL) | VAF 16/109 reads (15%) | catalogued as rs1568383502; called by mutect2, pindel, varscan2
- ZFYVE1 | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.041); catalogued as COSV59609968; called by muse, mutect2, varscan2
- ZNF133 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs149645929; called by muse, mutect2, varscan2
- ZNF197 | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as rs1232001366, COSV60359751; called by muse, mutect2, varscan2
- ZNF234 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as rs376364041; called by muse, mutect2, varscan2
- ZNF280C | c.1076A>G p.Y359C | Missense Mutation (SNP) | VAF 15/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100921201; called by muse, mutect2
- ZNF3 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780317788, COSV52796163; called by muse, mutect2, varscan2
- ZNF526 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.333); catalogued as rs149858475; called by muse, mutect2, varscan2
- ZNF618 | c.2584G>A p.A862T (on ENST00000374126 / NM_001318042.2; = p.A769T on NM_133374.2) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs372290471; called by muse, mutect2, varscan2
- ZNF621 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.892); catalogued as rs144763141; called by muse, mutect2, varscan2
- ZNF709 | c.1822C>T p.R608* | Nonsense Mutation (SNP) | VAF 31/96 reads (32%) | catalogued as rs1310921645; called by muse, mutect2, varscan2
- ZNF737 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.558); catalogued as COSV101417597; called by muse, mutect2
- ABCA2 | c.874C>T p.Q292* (on ENST00000614293; = p.Q262* on NM_001606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 45/146 reads (31%) | called by muse, mutect2, varscan2
- AGBL1 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AICDA | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- AKAP9 | c.2602T>C p.Y868H | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- AP1M2 | c.593T>C p.I198T | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ATP13A3 | c.2900A>G p.Q967R | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- BCORL1 | c.5069T>C p.V1690A | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- BIN1 | c.1262A>G p.E421G | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- BORCS5 | c.482T>C p.M161T | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- BRF2 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- C1R | c.1831G>A p.G611R (on ENST00000536053 / NM_001354346.2; = p.G597R on NM_001733.7) | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C8orf48 | c.81C>G p.N27K | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC144A | c.578A>T p.D193V | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2
- CCT8L2 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CDC42BPA | c.83T>C p.V28A | Missense Mutation (SNP) | VAF 84/108 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, varscan2
- CECR2 | c.3418T>C p.Y1140H (on ENST00000342247 / NM_001290047.2; = p.Y956H on NM_001290046.1) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEP250 | c.98A>C p.E33A | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- CFAP206 | c.1718A>G p.Y573C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CHD7 | c.6758A>G p.E2253G | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- CHORDC1 | c.952C>A p.P318T | Missense Mutation (SNP) | VAF 90/160 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CIART | c.815G>A p.S272N | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- CIT | c.4618A>G p.T1540A | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CNTN2 | c.2696C>T p.A899V | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- COBLL1 | c.836del p.F279Sfs*22 (on ENST00000392717; = p.F241Sfs*22 on NM_014900.5) | Frame Shift Del (DEL) | VAF 34/67 reads (51%) | called by mutect2, pindel, varscan2
- COL5A1 | c.4491G>T p.Q1497H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CRYBG3 | c.7352G>A p.G2451E | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- CST5 | c.245T>C p.V82A | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- CUL9 | c.2708T>C p.I903T | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DLG1 | c.2377G>A p.V793I (on ENST00000419354 / NM_001290983.1; = p.V815I on NM_004087.2) | Missense Mutation (SNP) | VAF 81/99 reads (82%) | SIFT tolerated (0.35); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- DNMT1 | c.4670A>G p.Q1557R | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DUSP9 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ELOA2 | c.407C>A p.P136H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FAM110A | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM50B | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- FGB | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, varscan2
- GADL1 | c.1496G>A p.S499N | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GPR179 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 38/51 reads (75%) | SIFT tolerated (0.35); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- GRIN2D | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRM8 | c.2331C>A p.F777L | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- HDAC9 | c.2825C>T p.T942I | Missense Mutation (SNP) | VAF 76/170 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HECTD1 | c.2888C>T p.A963V | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- HMGXB3 | c.1972G>A p.E658K (on ENST00000613459; = p.E412K on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- HOOK3 | c.2023A>G p.T675A | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HOXC13 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- ITSN1 | c.5129T>C p.V1710A | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- KANK4 | c.1130T>A p.I377N | Missense Mutation (SNP) | VAF 110/134 reads (82%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- KIF18A | c.889G>C p.D297H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- KNL1 | c.4403A>G p.Q1468R (on ENST00000346991 / NM_170589.5; = p.Q1442R on NM_144508.5) | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.299); called by muse, mutect2
- LAMB1 | c.1663T>C p.Y555H | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- LINGO2 | c.1637C>A p.A546D | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- LMTK3 | c.1894C>T p.R632W | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- LTN1 | c.4691C>T p.A1564V | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MAP4K1 | c.1657A>G p.M553V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MORC2 | c.2672G>A p.C891Y (on ENST00000397641 / NM_001303256.3; = p.C829Y on NM_014941.3) | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- NACC2 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.048); called by muse, varscan2
- NEFL | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NEK9 | c.2474C>A p.P825H | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NFIA | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 66/78 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- NLGN4X | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 134/150 reads (89%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NOX3 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NR3C1 | c.2224G>A p.D742N | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- NYAP1 | c.548G>A p.G183D | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.018); called by muse, varscan2
- OXER1 | c.1139T>C p.V380A | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- PCDHB9 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 72/134 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- PCDHGB5 | c.2006C>T p.P669L | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- PDE4DIP | c.4232G>A p.S1411N | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by mutect2, varscan2
- PGBD2 | c.992T>C p.V331A | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PHIP | c.1699C>T p.R567C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PLA2G4B | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- PLBD2 | c.1560C>A p.F520L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- PLEKHA1 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 28/45 reads (62%) | called by muse, mutect2, varscan2
- PNPLA7 | c.3824C>T p.A1275V | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- POLR1A | c.545A>C p.K182T | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- PRKCB | c.236A>G p.H79R | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- R3HDM2 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RAI14 | c.1091A>G p.K364R | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RBCK1 | c.329A>T p.D110V (on ENST00000356286 / NM_031229.4; = p.D68V on NM_006462.6) | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- RNF10 | c.1195C>A p.L399M | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RPL8 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- RPS6KA5 | c.1308T>G p.S436R | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- S1PR4 | c.533T>G p.M178R | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- SCNN1A | c.808C>A p.L270M | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- SECISBP2L | c.1610C>A p.P537H (on ENST00000559471 / NM_001193489.2; = p.P492H on NM_014701.4) | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- SEMA4G | c.2098T>C p.C700R (on ENST00000370250; = p.C705R on NM_017893.3) | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SH2D2A | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIN3B | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- SLC39A7 | c.411T>C p.Y137= | Splice Region (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- STT3B | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT tolerated (0.58); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYBU | c.1345A>G p.T449A (on ENST00000276646 / NM_001099754.2; = p.T448A on NM_017786.6) | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by mutect2, varscan2
- TEP1 | c.2804G>T p.S935I | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- TRIM58 | c.806T>C p.I269T | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TSEN34 | c.604T>C p.W202R | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- TTC12 | c.24T>A p.D8E | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- TYK2 | c.599T>C p.I200T | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.044); called by muse, varscan2
- UBD | c.138G>T p.Q46H | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- UBN2 | c.3360_3362del p.S1120del | In Frame Del (DEL) | VAF 50/128 reads (39%) | called by pindel, varscan2
- URGCP | c.1390G>A p.E464K (on ENST00000453200 / NM_001077663.3; = p.E455K on NM_017920.4) | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- VEZT | c.2275A>G p.T759A | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- YY1AP1 | c.2302T>C p.S768P (on ENST00000295566 / NM_139118.2; = p.S711P on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- Z83844.2 | c.1646T>C p.L549P | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZDHHC17 | c.1139A>G p.N380S | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZFHX4 | c.9757G>A p.D3253N | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZNF318 | c.3337G>A p.A1113T | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF318 | c.1996G>T p.A666S | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF512B | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF628 | c.3037G>A p.A1013T | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF646 | c.2702G>A p.R901H | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF773 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF878 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- ABCA2 | c.4242C>T p.G1414= (on ENST00000614293; = p.G1384= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs567851206; called by muse, mutect2, varscan2
- AHNAK | c.14958C>T p.S4986= | Silent (SNP) | VAF 52/100 reads (52%) | catalogued as rs1389721187; called by muse, mutect2, varscan2
- AMH | c.165C>T p.C55= | Silent (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- ANGPTL2 | c.141G>A p.A47= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs933882845, COSV52232852; called by muse, mutect2, varscan2
- ANKRD6 | c.1113T>C p.P371= | Silent (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- AQP1 | c.135G>A p.A45= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs781356338; called by muse, mutect2
- ARAP1 | c.3738C>T p.H1246= (on ENST00000393609 / NM_001040118.2; = p.H1001= on NM_015242.4) | Silent (SNP) | VAF 27/47 reads (57%) | catalogued as rs745998343; called by muse, mutect2, varscan2
- ASIC3 | c.741G>A p.P247= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as rs149333074; called by muse, mutect2, varscan2
- ATP11C | c.648G>A p.Q216= | Silent (SNP) | VAF 52/56 reads (93%) | catalogued as rs376810884; called by muse, varscan2
- BACH2 | c.267G>A p.P89= | Silent (SNP) | VAF 44/52 reads (85%) | catalogued as rs771556236; called by muse, mutect2
- BCAS1 | c.1053C>T p.S351= | Silent (SNP) | VAF 47/188 reads (25%) | catalogued as rs751429839; called by muse, mutect2, varscan2
- BCAS3 | c.2508C>T p.C836= (on ENST00000390652 / NM_001353144.2; = p.C821= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs1315172358; called by muse, mutect2, varscan2
- BEST2 | c.360C>T p.R120= | Silent (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- BOD1L1 | c.8190C>T p.S2730= | Silent (SNP) | VAF 17/134 reads (13%) | catalogued as rs555836394, COSV50027326; called by muse, mutect2, varscan2
- BTBD16 | c.645C>T p.Y215= | Silent (SNP) | VAF 29/49 reads (59%) | catalogued as rs761412759; called by muse, mutect2, varscan2
- C10orf71 | c.3813C>T p.P1271= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs1258933199; called by muse, mutect2
- C1orf174 | c.327C>T p.G109= | Silent (SNP) | VAF 61/68 reads (90%) | catalogued as rs368113639; called by muse, mutect2, varscan2
- C2orf16 | c.3009G>A p.T1003= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs370553692; called by muse, mutect2, varscan2
- C9orf64 | c.180C>T p.A60= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV59032367; called by muse, mutect2, varscan2
- CACNA1D | c.2019C>T p.G673= (on ENST00000350061 / NM_001128840.3; = p.G693= on NM_000720.4) | Silent (SNP) | VAF 89/199 reads (45%) | catalogued as rs562114124; called by muse, mutect2, varscan2
- CACNA1S | c.639C>T p.I213= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as rs1229722414, COSV62938408; ClinVar: likely benign; called by muse, mutect2, varscan2
- CAND2 | c.2310G>A p.P770= (on ENST00000456430 / NM_001162499.2; = p.P677= on NM_012298.3) | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as rs371560476; called by muse, mutect2, varscan2
- CASZ1 | c.2268C>T p.A756= | Silent (SNP) | VAF 47/58 reads (81%) | catalogued as rs372443290; called by muse, mutect2, varscan2
- CCDC22 | c.1788C>T p.G596= | Silent (SNP) | VAF 102/113 reads (90%) | catalogued as COSV100873100; called by muse, mutect2, varscan2
- CCNP | c.501C>T p.C167= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs1361970727, COSV55687748; called by mutect2, varscan2
- CDCA2 | c.1224G>A p.L408= | Silent (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- CENPM | c.300C>T p.L100= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as rs754236730, COSV53244647; called by muse, mutect2, varscan2
- CEP152 | c.4842C>T p.S1614= (on ENST00000380950 / NM_001194998.2; = p.S1558= on NM_014985.4) | Silent (SNP) | VAF 26/142 reads (18%) | catalogued as rs765678153, COSV100358550; called by muse, mutect2, varscan2
- CGGBP1 | c.81C>T p.V27= | Silent (SNP) | VAF 65/122 reads (53%) | called by muse, mutect2, varscan2
- CHAF1A | c.753G>A p.P251= | Silent (SNP) | VAF 35/61 reads (57%) | catalogued as rs768787420, COSV56675212; called by muse, mutect2, varscan2
- CHRNA4 | c.1218G>A p.P406= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as rs200528988, COSV64719097; called by muse, mutect2, varscan2
- CKB | c.162C>T p.D54= | Silent (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2
- COL28A1 | c.1914C>T p.G638= | Silent (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- COX4I2 | c.279G>A p.A93= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as rs754885839; called by muse, mutect2, varscan2
- CSGALNACT1 | c.30G>A p.A10= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs775732600; called by muse, mutect2, varscan2
- CSPG4 | c.2697G>A p.A899= | Silent (SNP) | VAF 46/107 reads (43%) | catalogued as rs144209551; called by muse, mutect2, varscan2
- CTIF | c.135G>A p.T45= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as rs769047846, COSV56484255; called by muse, mutect2, varscan2
- CTTNBP2 | c.2787A>G p.L929= | Silent (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- DAB2 | c.1743C>A p.P581= | Silent (SNP) | VAF 9/148 reads (6%) | called by muse, mutect2
- DDR1 | c.1662C>T p.G554= (on ENST00000324771; = p.G517= on NM_001954.4) | Silent (SNP) | VAF 93/132 reads (70%) | catalogued as rs756028903; called by muse, mutect2, varscan2
- DMTN | c.48C>T p.S16= | Silent (SNP) | VAF 28/93 reads (30%) | called by muse, mutect2, varscan2
- DOCK1 | c.4500G>A p.T1500= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as rs779414287; called by muse, mutect2
- DOCK3 | c.2802G>A p.P934= | Silent (SNP) | VAF 20/361 reads (6%) | catalogued as rs370843265; called by muse, mutect2
- DPYSL2 | c.1686C>T p.P562= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs747715290, COSV60782498; called by muse, mutect2
- DTNB | c.828C>T p.A276= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs373794202; called by muse, mutect2, varscan2
- EHD4 | c.1377G>A p.S459= | Silent (SNP) | VAF 20/155 reads (13%) | catalogued as rs757361549, COSV99587826; called by muse, mutect2, varscan2
- EIF4G1 | c.669G>A p.T223= (on ENST00000346169 / NM_198241.3; = p.T27= on NM_004953.5) | Silent (SNP) | VAF 41/53 reads (77%) | catalogued as rs1366543204; called by muse, mutect2, varscan2
- ELAVL3 | c.609G>A p.A203= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as rs547655016, COSV63646052; called by muse, mutect2, varscan2
- EPHA8 | c.387G>A p.S129= | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as COSV51262387, COSV51282460; called by muse, mutect2
- ESPL1 | c.5577C>T p.Y1859= | Silent (SNP) | VAF 22/119 reads (18%) | catalogued as rs527909578, COSV99229002; called by muse, mutect2, varscan2
- EYA1 | c.1236A>G p.A412= | Silent (SNP) | VAF 74/159 reads (47%) | called by muse, mutect2, varscan2
- FAT3 | c.961T>C p.L321= | Silent (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2, varscan2
- FBN1 | c.8496T>C p.S2832= | Silent (SNP) | VAF 28/342 reads (8%) | catalogued as rs1216871823; called by muse, mutect2
- FBN1 | c.5184G>A p.A1728= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as rs754660497; called by muse, mutect2, varscan2
- FBXO3 | c.1017C>T p.D339= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs1019777059; called by muse, mutect2, varscan2
- FCGBP | c.10197C>T p.R3399= | Silent (SNP) | VAF 37/84 reads (44%) | called by muse, mutect2, varscan2
- FCGBP | c.7095G>A p.S2365= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as rs1458831392; called by muse, mutect2, varscan2
- FFAR2 | c.871C>T p.L291= | Silent (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- FOXI3 | c.453G>A p.S151= | Silent (SNP) | VAF 23/31 reads (74%) | catalogued as COSV101230925; called by muse, mutect2, varscan2
- FRAS1 | c.1785C>T p.G595= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs557214616, COSV53600870; called by muse, mutect2, varscan2
- GALNT10 | c.1608C>T p.Y536= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as rs368630751; called by muse, varscan2
- GARS1 | c.1545G>A p.V515= | Silent (SNP) | VAF 76/159 reads (48%) | catalogued as rs1001474075, COSV66828664; called by muse, mutect2, varscan2
- GASK1B | c.1011G>A p.Q337= | Silent (SNP) | VAF 44/123 reads (36%) | catalogued as rs1304888491; called by muse, mutect2, varscan2
- GPAA1 | c.801G>A p.T267= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs189367473; called by muse, mutect2, varscan2
- GPR27 | c.1065C>T p.C355= | Silent (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- GREB1L | c.2937C>T p.R979= | Silent (SNP) | VAF 27/134 reads (20%) | catalogued as rs1012887577; called by muse, mutect2, varscan2
- GTF3C4 | c.522C>T p.C174= | Silent (SNP) | VAF 37/68 reads (54%) | catalogued as rs372437145; called by muse, mutect2, varscan2
- GTF3C5 | c.408G>A p.T136= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs575422131; called by muse, mutect2, varscan2
- GYS1 | c.1779C>T p.S593= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs372542706; called by muse, mutect2, varscan2
- HDAC7 | c.1803C>T p.N601= (on ENST00000427332; = p.N640= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs138164422; called by muse, mutect2, varscan2
- HS3ST1 | c.126C>T p.R42= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs778355639, COSV50024385; called by muse, mutect2, varscan2
- HSPA1A | c.1410C>T p.G470= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs1388916045; called by muse, mutect2, varscan2
- HTR6 | c.1275C>T p.P425= | Silent (SNP) | VAF 60/76 reads (79%) | catalogued as rs201218739, COSV53869051; called by muse, mutect2, varscan2
- HTT | c.576G>A p.E192= | Silent (SNP) | VAF 44/138 reads (32%) | called by muse, mutect2, varscan2
- IFT140 | c.3015C>T p.N1005= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs767092157, COSV54154661; called by muse, mutect2, varscan2
- IGHD | c.726C>T p.N242= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as rs560469534, COSV66655397; called by muse, mutect2, varscan2
- IGSF9B | c.1485G>A p.T495= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2
- IL2RA | c.456C>T p.C152= | Silent (SNP) | VAF 66/89 reads (74%) | catalogued as rs377104035, COSV56921375; ClinVar: likely benign; called by muse, mutect2, varscan2
- ILF3 | c.2031C>T p.Y677= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs1234258543, COSV51562258; called by muse, mutect2
- INCENP | c.1158G>A p.A386= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs562346092, COSV53917766; called by muse, mutect2, varscan2
- INSRR | c.2679C>A p.T893= | Silent (SNP) | VAF 30/76 reads (39%) | called by muse, mutect2, varscan2
- IRX6 | c.156C>T p.Y52= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as rs779816494; called by muse, mutect2, varscan2
- ITGAE | c.2218C>T p.L740= | Silent (SNP) | VAF 23/29 reads (79%) | catalogued as COSV99560579; called by muse, mutect2, varscan2
- ITPR2 | c.6774A>G p.T2258= | Silent (SNP) | VAF 20/82 reads (24%) | called by muse, mutect2, varscan2
- ITPRIPL2 | c.1056A>C p.A352= | Silent (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- JAM3 | c.108C>A p.S36= | Silent (SNP) | VAF 4/70 reads (6%) | catalogued as COSV100137919; called by muse, mutect2
- JMJD4 | c.882C>T p.G294= | Silent (SNP) | VAF 42/52 reads (81%) | called by muse, mutect2, varscan2
- JRK | c.867G>A p.P289= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs781939281, COSV70629838; called by muse, mutect2, varscan2
- KCNG3 | c.234C>T p.R78= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100044829; called by muse, mutect2, varscan2
- KCNH2 | c.2109C>T p.H703= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs202214833; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNIP1 | c.9C>T p.A3= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as rs778210728; called by muse, varscan2
- KCNJ5 | c.90C>T p.R30= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs201886526, COSV100610491; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNQ2 | c.1077G>A p.T359= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs997179306; called by muse, mutect2, varscan2
- KLHL42 | c.423G>A p.G141= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV101179711; called by muse, mutect2, varscan2
- KMT5B | c.1917C>T p.D639= | Silent (SNP) | VAF 59/124 reads (48%) | catalogued as rs149239650; called by muse, mutect2, varscan2
- KRT6C | c.483C>T p.A161= | Silent (SNP) | VAF 58/130 reads (45%) | catalogued as rs769888167; called by muse, mutect2, varscan2
- KRTAP9-9 | c.276C>T p.G92= | Silent (SNP) | VAF 57/70 reads (81%) | catalogued as rs745862757, COSV101223498; called by muse, mutect2, varscan2
- LAMA3 | c.5511C>T p.G1837= (on ENST00000313654 / NM_198129.4; = p.G228= on NM_000227.6) | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs754251072; called by muse, mutect2, varscan2
- LIFR | c.828A>G p.K276= | Silent (SNP) | VAF 14/158 reads (9%) | catalogued as COSV99663575; called by muse, mutect2
- LOXHD1 | c.6729C>T p.S2243= (on ENST00000642948; = p.S2181= on NM_144612.7) | Silent (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- LRP4 | c.2118C>T p.N706= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs762032159; called by muse, mutect2, varscan2
- LYPD3 | c.1002A>G p.A334= | Silent (SNP) | VAF 15/65 reads (23%) | called by muse, mutect2, varscan2
- MACF1 | c.21951C>T p.A7317= (on ENST00000372915; = p.A5362= on NM_012090.5) | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs201356281; called by muse, mutect2, varscan2
- MAGEL2 | c.3519T>A p.P1173= | Silent (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- MARF1 | c.2862C>T p.H954= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as rs533235779, COSV60028058; called by muse, mutect2, varscan2
- MEGF11 | c.1875C>T p.C625= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as rs146260891; called by muse, mutect2, varscan2
- MKS1 | c.759G>A p.T253= | Silent (SNP) | VAF 25/37 reads (68%) | catalogued as rs770140009, COSV100439681, COSV58305697; ClinVar: likely benign; called by muse, mutect2, varscan2
- MMP9 | c.1395G>A p.P465= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs768338998, COSV63434320; called by muse, mutect2, varscan2
- MOB3C | c.189C>T p.H63= | Silent (SNP) | VAF 5/70 reads (7%) | catalogued as rs936571990; called by muse, mutect2
- MON1B | c.1014C>A p.A338= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV99941589; called by muse, mutect2
- MROH5 | c.2259C>T p.R753= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs757166300, COSV101435940; called by muse, mutect2, varscan2
- MYL10 | c.498C>T p.F166= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as rs767875981, COSV56208889; called by muse, mutect2, varscan2
- MYOF | c.703A>C p.R235= | Silent (SNP) | VAF 37/60 reads (62%) | called by muse, mutect2, varscan2
- NBEA | c.3144A>G p.V1048= | Silent (SNP) | VAF 40/107 reads (37%) | called by muse, mutect2, varscan2
- NCOA7 | c.1443G>A p.A481= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs375161871; called by muse, mutect2, varscan2
- NDUFAF3 | c.234C>A p.P78= | Silent (SNP) | VAF 50/115 reads (43%) | called by muse, mutect2, varscan2
- NFIX | c.930C>T p.S310= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs1413684794, COSV62177680; called by muse, mutect2, varscan2
- NHSL2 | c.2049C>T p.G683= (on ENST00000510661; = p.G1049= on NM_001013627.2) | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as rs1382647776, COSV65452935; called by muse, mutect2, varscan2
- NKX2-4 | c.639C>T p.Y213= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV100698579; called by muse, mutect2, varscan2
- NLRP1 | c.3174C>T p.C1058= | Silent (SNP) | VAF 41/54 reads (76%) | catalogued as rs1397225075, COSV52565814; called by muse, mutect2, varscan2
- NNT | c.219A>G p.A73= | Silent (SNP) | VAF 32/133 reads (24%) | called by muse, mutect2, varscan2
- NOP14 | c.1386C>T p.L462= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs1270112660, COSV58624966; called by muse, mutect2, varscan2
- NPAS3 | c.690C>T p.A230= (on ENST00000356141 / NM_001164749.2; = p.A198= on NM_022123.3) | Silent (SNP) | VAF 28/58 reads (48%) | called by muse, mutect2, varscan2
- NR4A1 | c.960G>A p.Q320= | Silent (SNP) | VAF 49/136 reads (36%) | called by muse, mutect2, varscan2
- NRG2 | c.1026C>A p.A342= | Silent (SNP) | VAF 14/80 reads (18%) | called by mutect2, varscan2
- NT5C1B | c.1680C>T p.D560= (on ENST00000359846 / NM_001199086.2; = p.D500= on NM_033253.4) | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs772615000, COSV100409831; called by muse, mutect2, varscan2
- NTNG2 | c.570G>A p.A190= | Silent (SNP) | VAF 41/67 reads (61%) | catalogued as rs762414873; called by muse, mutect2, varscan2
- NYNRIN | c.2316C>T p.H772= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs751550646, COSV66844408; called by muse, mutect2, varscan2
- OR9A4 | c.756C>T p.Y252= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as rs782066072, COSV71884906, COSV71885528; called by muse, mutect2, varscan2
- PANK1 | c.711A>G p.P237= (on ENST00000307534 / NM_148977.2; = p.P12= on NM_138316.4) | Silent (SNP) | VAF 13/16 reads (81%) | catalogued as rs376656328; called by muse, mutect2, varscan2
- PARP14 | c.2628C>T p.H876= | Silent (SNP) | VAF 49/102 reads (48%) | catalogued as rs375197249; called by muse, mutect2, varscan2
- PCDHA11 | c.1440C>T p.D480= | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as rs1554164396, COSV56554757; called by muse, mutect2
- PCDHA8 | c.1437G>A p.A479= | Silent (SNP) | VAF 70/119 reads (59%) | catalogued as COSV65338300; called by muse, mutect2, varscan2
- PCDHA9 | c.1461C>T p.N487= | Silent (SNP) | VAF 8/152 reads (5%) | catalogued as COSV65323655; called by muse, mutect2
- PDE8B | c.960C>T p.S320= | Silent (SNP) | VAF 25/119 reads (21%) | catalogued as rs1285592009; called by muse, mutect2, varscan2
- PEDS1 | c.573G>A p.T191= | Silent (SNP) | VAF 72/140 reads (51%) | catalogued as rs1458626066; called by muse, mutect2, varscan2
- PHF8 | c.2169C>T p.G723= (on ENST00000357988 / NM_001184896.1; = p.G687= on NM_015107.3) | Silent (SNP) | VAF 46/56 reads (82%) | catalogued as rs781865695; called by muse, varscan2
- PI4KA | c.4740G>A p.P1580= | Silent (SNP) | VAF 17/145 reads (12%) | catalogued as rs777814861; called by muse, mutect2, varscan2
- PIH1D2 | c.927C>T p.I309= | Silent (SNP) | VAF 23/112 reads (21%) | called by muse, mutect2, varscan2
- PIP5KL1 | c.924G>A p.V308= (on ENST00000388747 / NM_001135219.2; = p.V105= on NM_173492.1) | Silent (SNP) | VAF 17/29 reads (59%) | called by muse, mutect2, varscan2
- PJA2 | c.639T>C p.T213= | Silent (SNP) | VAF 65/111 reads (59%) | called by muse, mutect2, varscan2
- PLEKHM2 | c.1326C>T p.P442= | Silent (SNP) | VAF 75/91 reads (82%) | catalogued as rs1405403941; called by muse, mutect2, varscan2
- PLEKHO2 | c.1296C>T p.G432= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV100060604; called by muse, mutect2, varscan2
- PLXNB2 | c.3228C>T p.D1076= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs756491902; called by muse, mutect2, varscan2
- PML | c.1017C>T p.Y339= | Silent (SNP) | VAF 36/76 reads (47%) | catalogued as rs749092993, COSV99167808; called by muse, varscan2
- PNPLA6 | c.1275C>T p.I425= (on ENST00000414982 / NM_001166111.2; = p.I377= on NM_006702.5) | Silent (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2
- POGZ | c.3996C>T p.P1332= | Silent (SNP) | VAF 56/124 reads (45%) | catalogued as rs769941353; called by muse, mutect2, varscan2
- PPL | c.2181C>T p.S727= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs772341543, COSV100630979; called by muse, mutect2
- PRDM1 | c.1215G>A p.S405= | Silent (SNP) | VAF 27/34 reads (79%) | catalogued as COSV64845685; called by muse, mutect2, varscan2
- PRDM2 | c.2934G>A p.P978= | Silent (SNP) | VAF 81/98 reads (83%) | catalogued as rs1403926467, COSV99342527; called by muse, mutect2, varscan2
- PRRC2B | c.1362G>A p.P454= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs565217318, COSV100621538, COSV61944517; called by muse, mutect2, varscan2
- PRRG1 | c.561A>G p.E187= | Silent (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- PTGER4 | c.621C>T p.C207= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV56720687; called by muse, mutect2, varscan2
- PTPN21 | c.1842G>A p.A614= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs763825175, COSV100161637; called by muse, varscan2
- PTPRD | c.2994G>A p.T998= | Silent (SNP) | VAF 31/130 reads (24%) | called by muse, mutect2, varscan2
- QSOX1 | c.279C>A p.A93= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- QTRT1 | c.477C>T p.D159= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as rs151104617; called by muse, mutect2, varscan2
- RAB6B | c.513G>A p.A171= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as rs370450177, COSV53316019; called by muse, mutect2, varscan2
- RABL6 | c.804C>T p.Y268= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs765117424; called by muse, mutect2
- RARA | c.1371G>T p.P457= | Silent (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- RASSF4 | c.657C>T p.F219= | Silent (SNP) | VAF 25/41 reads (61%) | catalogued as rs192302639; called by muse, mutect2, varscan2
- RBM42 | c.186G>A p.A62= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs1342706517; called by muse, mutect2, varscan2
- RIN1 | c.1440C>T p.F480= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs760861873; called by muse, mutect2
- RNF213 | c.8769C>T p.L2923= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs768365997; called by muse, mutect2, varscan2
- ROBO1 | c.4155C>T p.S1385= | Silent (SNP) | VAF 63/151 reads (42%) | catalogued as rs536505138, COSV71394481; ClinVar: likely benign; called by muse, mutect2, varscan2
- RTL10 | c.69C>T p.N23= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as rs376068168; called by muse, mutect2, varscan2
- SART1 | c.1779C>T p.N593= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs756777909; called by muse, mutect2, varscan2
- SELENBP1 | c.513C>T p.F171= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs767636146; called by muse, mutect2, varscan2
- SIGLEC7 | c.414G>A p.Q138= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs541602063; called by muse, mutect2, varscan2
- SLC1A6 | c.1446G>A p.S482= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as rs759196664, COSV55670797; called by muse, mutect2, varscan2
- SLC26A1 | c.1080G>A p.A360= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs761530861; called by muse, mutect2, varscan2
- SLC2A3 | c.456T>A p.G152= | Silent (SNP) | VAF 89/525 reads (17%) | called by muse, mutect2, varscan2
- SLC5A10 | c.1518C>T p.A506= (on ENST00000395645 / NM_001042450.4; = p.A522= on NM_152351.5) | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs745918115, COSV52413276; called by muse, mutect2, varscan2
- SLC6A2 | c.24G>A p.P8= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs778163877; called by muse, mutect2, varscan2
- SLIT3 | c.4320C>T p.G1440= | Silent (SNP) | VAF 43/79 reads (54%) | catalogued as rs758071143, COSV100265941; called by muse, mutect2, varscan2
- SMTNL2 | c.1074C>T p.L358= (on ENST00000389313 / NM_001114974.2; = p.L214= on NM_198501.3) | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs778357646; called by mutect2, varscan2
- SNX33 | c.1587C>T p.A529= | Silent (SNP) | VAF 50/106 reads (47%) | catalogued as rs752831144, COSV100415434; called by muse, mutect2, varscan2
- SOGA1 | c.732C>T p.D244= | Silent (SNP) | VAF 39/75 reads (52%) | catalogued as rs751253388; called by muse, mutect2, varscan2
- SPATS1 | c.543G>A p.T181= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs371949352; called by muse, mutect2, varscan2
- SPTBN4 | c.6288G>A p.A2096= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as rs577033896; called by muse, mutect2, varscan2
- SRRT | c.1968C>T p.H656= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs747283824; called by muse, mutect2, varscan2
- ST3GAL3 | c.333G>A p.T111= (on ENST00000361392 / NM_174964.4; = p.T96= on NM_006279.5) | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs763879713, COSV99496090; called by muse, mutect2, varscan2
- STAB1 | c.4755C>T p.V1585= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs185967985; called by muse, mutect2, varscan2
- STEAP2 | c.156C>T p.C52= | Silent (SNP) | VAF 78/182 reads (43%) | catalogued as rs777545171, COSV55289645; called by muse, mutect2, varscan2
- STYXL2 | c.639G>A p.A213= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs573463190, COSV54808823, COSV99608432; called by muse, mutect2, varscan2
- SULT1A2 | c.684G>A p.S228= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as rs141569114; called by muse, mutect2, varscan2
- SUPT16H | c.993C>T p.D331= | Silent (SNP) | VAF 39/164 reads (24%) | catalogued as rs779264792, COSV53528314, COSV53528572; called by muse, mutect2, varscan2
- SYNPO2 | c.1323C>T p.S441= | Silent (SNP) | VAF 37/114 reads (32%) | called by muse, mutect2, varscan2
- SYT17 | c.1167T>C p.N389= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV100810551; called by muse, mutect2, varscan2
- TACC3 | c.2379G>A p.A793= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs148572882; called by mutect2, varscan2
- TAF10 | c.312C>T p.N104= | Silent (SNP) | VAF 10/44 reads (23%) | called by mutect2, varscan2
- TBC1D20 | c.702C>T p.H234= | Silent (SNP) | VAF 40/83 reads (48%) | catalogued as rs774695887, COSV100830455; called by muse, mutect2, varscan2
- TCF3 | c.936C>T p.S312= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs377363979; called by muse, mutect2
- TET3 | c.4044C>T p.D1348= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs530077169, COSV69644617; called by muse, mutect2, varscan2
- TEX10 | c.2736C>T p.N912= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as rs373037476; called by muse, mutect2, varscan2
- TEX2 | c.255C>T p.P85= | Silent (SNP) | VAF 68/87 reads (78%) | catalogued as rs782655334; called by muse, mutect2, varscan2
- TIAM2 | c.363C>T p.H121= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs775119632; called by muse, mutect2, varscan2
- TLNRD1 | c.948C>T p.G316= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs766193281, COSV99146089; called by muse, mutect2, varscan2
- TMEM184A | c.690C>T p.S230= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as rs368580121; called by muse, mutect2
- TP63 | c.414C>T p.H138= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs766239462, COSV53197864; called by muse, mutect2, varscan2
- TSKU | c.93C>T p.F31= | Silent (SNP) | VAF 36/56 reads (64%) | catalogued as rs761387735, COSV60751759; called by muse, varscan2
- TTN | c.25578G>A p.T8526= (on ENST00000591111; = p.T7599= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 63/90 reads (70%) | catalogued as rs747558822, COSV60019924, COSV60069038; called by muse, mutect2, varscan2
- UBAP1L | c.783G>A p.A261= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as rs185974312; called by muse, mutect2, varscan2
- UCKL1 | c.1416C>T p.H472= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs1424166227; called by muse, mutect2, varscan2
- UCP1 | c.816A>G p.V272= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs1346034290; called by muse, mutect2, varscan2
- XIRP2 | c.1758C>T p.D586= (on ENST00000628543; = p.D761= on NM_152381.6) | Silent (SNP) | VAF 48/70 reads (69%) | catalogued as rs763971750, COSV54725198; called by muse, varscan2
- ZBTB48 | c.1053G>A p.T351= | Silent (SNP) | VAF 27/34 reads (79%) | catalogued as rs764555455; called by muse, mutect2, varscan2
- ZBTB49 | c.1977C>T p.I659= | Silent (SNP) | VAF 26/91 reads (29%) | called by muse, mutect2, varscan2
52 further variants in this file (0 protein-altering or splice-affecting, 11 silent, 41 other) are not listed here.
